Somatic mutation profile of tumor specimen TARGET-20-PANVGE-09A (aliquot TARGET-20-PANVGE-09A-02D) from TARGET case TARGET-20-PANVGE, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.6 years (5,346 days).
Specimen TARGET-20-PANVGE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53ee39cc-20df-4fd5-9801-43130f7749ab.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANVGE-14A (Bone Marrow Normal), aliquot TARGET-20-PANVGE-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ad682ae-f76c-4455-a5c0-84875d44c91e

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>T p.D835Y | Missense Mutation (SNP) | VAF 110/296 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- WT1 | c.1106dup p.A370Gfs*3 | Frame Shift Ins (INS) | VAF 78/220 reads (35%) | catalogued as COSV60066438, COSV60071255, COSV60072670, COSV60072961, COSV60074589; called by mutect2, pindel, varscan2
